Surgical pathology report (de-identified scan), TCGA case TCGA-22-5480, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-22-5480-01A (Primary Tumor).

DIAGNOSIS:

Lung, left upper lobe, lobectomy: Grade 4 (of 4) squamous cell carcinoma forming a 2.0 x 2.0 x 1.5 cm mass located 1.8 cm away from the bronchial margin, which is negative for tumor histologically, as are multiple (10) intrapulmonary peribronchial lymph nodes and the visceral pleura.

Soft tissue, left hilar region, excision: Grade 4 (of 4) non-small cell carcinoma with squamous features.

Lung, left lower lobe, excision: Intraparenchymal lymph node, negative for neoplasm, but non-necrotizing granulomatous inflammation is present. The findings of special stains for microorganisms (AR,GMS) will be reported separately in an addendum.

Lymph nodes, superior mediastinal, aortic, inferior mediastinal, left lower lobe bronchus, excision: Multiple superior mediastinal (9 tracheobronchial), aortic (4 aortopulmonary, 3 anterior mediastinal), inferior mediastinal (5 subcarinal, 4 inferior pulmonary ligament) and (2) left lower lobe bronchus lymph nodes are negative for tumor.

Source: NCI Genomic Data Commons file f03b22ce-88ca-410b-b83e-cd65ca25cac1 (TCGA-22-5480.62C5D0AA-1DBD-456A-B16F-CB233BE02A88.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).